Somatic mutation profile of cancer-model specimen HCM-CSHL-0143-C20-85A (3D Organoid; aliquot HCM-CSHL-0143-C20-85A-01D-A77E-36), derived from the primary tumor of HCMI case HCM-CSHL-0143-C20, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Rectum, NOS; AJCC pathologic stage: Stage I; Tumor grade: G2; Age at diagnosis: 90 years or older (exact value withheld by GDC).
Specimen HCM-CSHL-0143-C20-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) cf89cbf8-6947-4c51-ba30-f48cfff1b45f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-CSHL-0143-C20-10A (Blood Derived Normal), aliquot HCM-CSHL-0143-C20-10A-01D-A77E-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/745b6d6e-1838-403e-9775-af71c192c402

The open-access MAF lists 110 somatic variants for this specimen: 74 protein-altering or splice-affecting, 28 silent, 8 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 67, Silent 28, 5'UTR 3, Nonsense Mutation 3, Frame Shift Del 3, 5'Flank 2, Intron 1, RNA 1, Splice Site 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APC | c.694C>T p.R232* | Nonsense Mutation (SNP) | VAF 169/340 reads (50%) | hotspot (GDC flag); catalogued as rs397515734, CM920029, COSV57320753; ClinVar: pathogenic; called by muse, mutect2, varscan2
- APC | c.4189G>T p.E1397* | Nonsense Mutation (SNP) | VAF 176/353 reads (50%) | hotspot (GDC flag); catalogued as CM992136, COSV57321785, COSV57346425; called by muse, mutect2, varscan2
- CDH1 | c.1565+2dup p.X522_splice | Splice Site (INS) | VAF 181/432 reads (42%) | catalogued as rs1555516200, CI085159, CI146398; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- ERBB2 | c.2524G>A p.V842I | Missense Mutation (SNP) | VAF 180/350 reads (51%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.906); catalogued as rs1057519738, COSV104371920, COSV54062791; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ERBB3 | c.310G>A p.V104M | Missense Mutation (SNP) | VAF 229/466 reads (49%) | hotspot (GDC flag); SIFT deleterious (0.05); PolyPhen possibly damaging (0.64); catalogued as rs1057519893, COSV57246387, COSV57246465, COSV57253558; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- FBXW7 | c.1513C>T p.R505C (on ENST00000281708 / NM_001349798.2; = p.R425C on NM_018315.5) | Missense Mutation (SNP) | VAF 242/515 reads (47%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs149680468, COSV55890969, COSV55891274, COSV55898451; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 183/361 reads (51%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- OTOGL | c.3760del p.Y1254Ifs*3 (on ENST00000547103; = p.Y1245Ifs*3 on NM_173591.4 and 2 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 24/60 reads (40%) | catalogued as rs1064795124; ClinVar: likely pathogenic; called by mutect2, pindel, varscan2
- BLVRB | c.136C>T p.R46W | Missense Mutation (SNP) | VAF 150/302 reads (50%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.525); catalogued as rs762544157; called by muse, mutect2, varscan2
- CACNA1H | c.6652C>T p.R2218C | Missense Mutation (SNP) | VAF 42/81 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs761083620, COSV52353706; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CD1E | c.430G>C p.G144R | Missense Mutation (SNP) | VAF 177/371 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63769908; called by muse, mutect2, varscan2
- CDH1 | c.2431A>C p.I811L | Missense Mutation (SNP) | VAF 161/336 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55741411; called by muse, mutect2, varscan2
- CEMIP | c.524A>G p.E175G | Missense Mutation (SNP) | VAF 364/763 reads (48%) | SIFT tolerated (0.26); PolyPhen benign (0.191); catalogued as COSV55000517; called by muse, mutect2, varscan2
- COL22A1 | c.4538G>A p.R1513Q | Missense Mutation (SNP) | VAF 121/233 reads (52%) | SIFT tolerated (0.11); PolyPhen benign (0.02); catalogued as rs200298766, COSV100278836, COSV57343458; called by muse, mutect2, varscan2
- CRYBG1 | c.3704C>T p.S1235L | Missense Mutation (SNP) | VAF 139/291 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1226140016; called by muse, mutect2, varscan2
- DDX54 | c.526C>T p.R176* | Nonsense Mutation (SNP) | VAF 182/352 reads (52%) | catalogued as rs767686054; called by muse, mutect2, varscan2
- DLC1 | c.3170C>T p.A1057V (on ENST00000276297 / NM_001348081.2; = p.A620V on NM_006094.5) | Missense Mutation (SNP) | VAF 91/195 reads (47%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.621); catalogued as COSV52298290; called by muse, mutect2, varscan2
- DUSP21 | c.416G>A p.R139H | Missense Mutation (SNP) | VAF 181/443 reads (41%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.56); catalogued as rs769190462, COSV59133879; called by muse, mutect2, varscan2
- DUSP9 | c.601G>A p.A201T | Missense Mutation (SNP) | VAF 242/534 reads (45%) | SIFT deleterious (0.04); PolyPhen benign (0.024); catalogued as COSV61438275; called by muse, mutect2, varscan2
- EPHA7 | c.407G>A p.R136K | Missense Mutation (SNP) | VAF 56/122 reads (46%) | SIFT tolerated (0.38); PolyPhen possibly damaging (0.722); catalogued as rs1251015381, COSV100992487; called by muse, mutect2
- FAM184A | c.1741G>A p.E581K | Missense Mutation (SNP) | VAF 101/218 reads (46%) | SIFT tolerated (0.07); PolyPhen benign (0.073); catalogued as rs766274838, COSV58851824; called by muse, mutect2, varscan2
- FAM81B | c.866G>A p.R289H | Missense Mutation (SNP) | VAF 146/332 reads (44%) | SIFT tolerated (0.94); PolyPhen benign (0.005); catalogued as rs746583579, COSV51982028; called by muse, mutect2, varscan2
- FRMPD1 | c.4472G>A p.R1491H | Missense Mutation (SNP) | VAF 168/322 reads (52%) | SIFT deleterious (0.04); PolyPhen benign (0.005); catalogued as rs780248862, COSV66703083; called by muse, mutect2, varscan2
- FRMPD3 | c.634C>T p.R212C | Missense Mutation (SNP) | VAF 84/184 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs751103095, COSV52193920; called by muse, mutect2
- FTHL17 | c.295G>A p.V99M | Missense Mutation (SNP) | VAF 167/379 reads (44%) | SIFT tolerated (0.14); PolyPhen benign (0.005); catalogued as rs758861598; called by muse, mutect2, varscan2
- FZR1 | c.827C>T p.A276V | Missense Mutation (SNP) | VAF 169/325 reads (52%) | SIFT tolerated (0.15); PolyPhen benign (0.084); catalogued as rs1341046528; called by muse, mutect2, varscan2
- GCM1 | c.634G>A p.V212I | Missense Mutation (SNP) | VAF 95/174 reads (55%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as rs762898529; called by muse, mutect2, varscan2
- GHR | c.1180A>G p.I394V | Missense Mutation (SNP) | VAF 182/365 reads (50%) | SIFT tolerated (0.13); PolyPhen benign (0.035); catalogued as rs749019259; called by muse, mutect2, varscan2
- GP5 | c.922G>T p.A308S | Missense Mutation (SNP) | VAF 68/144 reads (47%) | SIFT tolerated (0.44); PolyPhen benign (0.009); catalogued as rs201416119; called by muse, mutect2, varscan2
- GRIA1 | c.2698C>T p.P900S | Missense Mutation (SNP) | VAF 244/452 reads (54%) | SIFT tolerated, low confidence (0.45); PolyPhen benign (0); catalogued as rs1302659705; called by muse, mutect2, varscan2
- GRIK3 | c.2699G>A p.R900H | Missense Mutation (SNP) | VAF 92/189 reads (49%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.72); catalogued as rs765867454; called by muse, mutect2, varscan2
- HDAC7 | c.1111C>T p.P371S (on ENST00000427332; = p.P410S on NM_015401.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 118/226 reads (52%) | SIFT tolerated (0.57); PolyPhen benign (0.034); catalogued as COSV99317146; called by muse, mutect2, varscan2
- KATNIP | c.3932G>A p.R1311H | Missense Mutation (SNP) | VAF 152/338 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs757390970, COSV55172619; called by muse, mutect2, varscan2
- KCNC2 | c.587C>T p.A196V | Missense Mutation (SNP) | VAF 190/409 reads (46%) | SIFT tolerated (0.49); PolyPhen benign (0.003); catalogued as COSV100129849, COSV54365172; called by muse, mutect2, varscan2
- KLHL2 | c.1115C>T p.S372F | Missense Mutation (SNP) | VAF 221/501 reads (44%) | SIFT deleterious (0.04); PolyPhen benign (0.279); catalogued as COSV56976838; called by muse, mutect2, varscan2
- KMT2C | c.14464C>T p.R4822C | Missense Mutation (SNP) | VAF 86/158 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100071372; called by muse, mutect2, varscan2
- LPL | c.998G>A p.R333H | Missense Mutation (SNP) | VAF 228/451 reads (51%) | SIFT deleterious (0.01); PolyPhen benign (0.262); catalogued as rs144466625, CM1410362; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- LRWD1 | c.1562T>A p.I521N | Missense Mutation (SNP) | VAF 66/129 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1209573737; called by muse, mutect2, varscan2
- MGAM2 | c.2348G>A p.R783Q | Missense Mutation (SNP) | VAF 86/158 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1229672108; called by muse, mutect2, varscan2
- MSRB1 | c.172C>T p.R58C | Missense Mutation (SNP) | VAF 290/628 reads (46%) | SIFT tolerated (0.2); PolyPhen benign (0.006); catalogued as rs376757252; called by muse, mutect2, varscan2
- NPBWR1 | c.700C>T p.R234W | Missense Mutation (SNP) | VAF 309/663 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as rs567536404, COSV100488325; called by muse, mutect2, varscan2
- PIGG | c.1997G>A p.R666Q (on ENST00000453061 / NM_001127178.3; = p.R658Q on NM_017733.4) | Missense Mutation (SNP) | VAF 102/215 reads (47%) | SIFT deleterious (0.02); PolyPhen benign (0.341); catalogued as rs1162996177; called by muse, mutect2, varscan2
- PLCL1 | c.1319G>A p.R440Q | Missense Mutation (SNP) | VAF 53/95 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1559098498, COSV70821877; called by muse, mutect2, varscan2
- PLG | c.757C>T p.R253C | Missense Mutation (SNP) | VAF 359/757 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs767909495; called by muse, mutect2, varscan2
- PLOD2 | c.109G>A p.D37N | Missense Mutation (SNP) | VAF 237/494 reads (48%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as rs766155244; called by muse, mutect2, varscan2
- PRDM5 | c.1697C>T p.T566M | Missense Mutation (SNP) | VAF 288/628 reads (46%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.896); catalogued as rs371714829; called by muse, varscan2
- PURG | c.890G>A p.R297H | Missense Mutation (SNP) | VAF 140/300 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs767466974, COSV53296113; called by muse, mutect2, varscan2
- RASD2 | c.250C>T p.R84C | Missense Mutation (SNP) | VAF 78/157 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV53352886, COSV53353647; called by muse, mutect2, varscan2
- SETBP1 | c.3818C>T p.T1273M | Missense Mutation (SNP) | VAF 237/238 reads (100%) | SIFT deleterious (0.02); PolyPhen benign (0.251); catalogued as rs958733748; called by muse, mutect2, varscan2
- SMAD4 | c.1048G>T p.V350F | Missense Mutation (SNP) | VAF 127/127 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61688949; called by muse, mutect2, varscan2
- STOX2 | c.995C>T p.A332V | Missense Mutation (SNP) | VAF 129/268 reads (48%) | SIFT tolerated (0.46); PolyPhen probably damaging (0.972); catalogued as rs749643820; called by muse, mutect2, varscan2
- TCF15 | c.463G>A p.A155T | Missense Mutation (SNP) | VAF 147/151 reads (97%) | SIFT tolerated (0.55); PolyPhen benign (0); catalogued as rs1354210845; called by muse, mutect2, varscan2
- TENM4 | c.8030C>T p.T2677I | Missense Mutation (SNP) | VAF 88/180 reads (49%) | SIFT tolerated (1); PolyPhen benign (0.07); catalogued as rs761318240; called by muse, mutect2, varscan2
- TNPO1 | c.1388G>A p.R463H | Missense Mutation (SNP) | VAF 217/505 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs370903533; called by muse, mutect2, varscan2
- TRPM8 | c.2408C>T p.T803M | Missense Mutation (SNP) | VAF 74/184 reads (40%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.636); catalogued as rs200017552, COSV61222595; called by muse, mutect2, varscan2
- ZBTB10 | c.1133A>C p.H378P | Missense Mutation (SNP) | VAF 108/255 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100990164; called by muse, mutect2, varscan2
- ZNF398 | c.931C>T p.R311C (on ENST00000475153 / NM_170686.3; = p.R140C on NM_020781.4) | Missense Mutation (SNP) | VAF 123/288 reads (43%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as rs199601006, COSV60066317; called by muse, mutect2, varscan2
- C1orf94 | c.976G>A p.A326T (on ENST00000488417 / NM_001134734.2; = p.A136T on NM_032884.5) | Missense Mutation (SNP) | VAF 143/261 reads (55%) | SIFT tolerated (0.19); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- CCDC87 | c.2027A>G p.K676R | Missense Mutation (SNP) | VAF 244/473 reads (52%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.591); called by muse, mutect2, varscan2
- DHX37 | c.1847G>A p.C616Y | Missense Mutation (SNP) | VAF 65/148 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- KLHL4 | c.1797G>T p.L599F | Missense Mutation (SNP) | VAF 114/256 reads (45%) | SIFT tolerated (0.29); PolyPhen benign (0.278); called by muse, mutect2, varscan2
- LATS1 | c.1009A>C p.K337Q | Missense Mutation (SNP) | VAF 323/627 reads (52%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.915); called by muse, mutect2, varscan2
- MRPS9 | c.1089G>T p.W363C | Missense Mutation (SNP) | VAF 31/76 reads (41%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.942); called by muse, mutect2, varscan2
- MUC16 | c.18226C>A p.P6076T | Missense Mutation (SNP) | VAF 257/563 reads (46%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.087); called by muse, mutect2, varscan2
- MYORG | c.1945C>G p.R649G | Missense Mutation (SNP) | VAF 212/455 reads (47%) | SIFT tolerated (0.21); PolyPhen benign (0.43); called by muse, mutect2, varscan2
- NDST1 | c.721G>T p.A241S | Missense Mutation (SNP) | VAF 127/279 reads (46%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.458); called by muse, mutect2, varscan2
- NUDT14 | c.166G>C p.V56L | Missense Mutation (SNP) | VAF 145/149 reads (97%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.77); called by muse, mutect2, varscan2
- POTEE | c.524C>A p.T175N | Missense Mutation (SNP) | VAF 224/545 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.937); called by muse, mutect2, varscan2
- RIMBP3 | c.2301_2302del p.E767Dfs*21 | Frame Shift Del (DEL) | VAF 110/1159 reads (9%) | called by pindel, varscan2
- RIMS4 | c.514del p.V172Sfs*27 | Frame Shift Del (DEL) | VAF 119/263 reads (45%) | called by mutect2, pindel, varscan2
- SLC25A25 | c.316T>G p.S106A | Missense Mutation (SNP) | VAF 146/311 reads (47%) | SIFT tolerated (0.66); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- SLCO4C1 | c.259T>C p.S87P | Missense Mutation (SNP) | VAF 21/376 reads (6%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- TGFBR2 | c.1496A>G p.E499G | Missense Mutation (SNP) | VAF 297/651 reads (46%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.627); called by muse, mutect2, varscan2
- WNK1 | c.271A>G p.T91A | Missense Mutation (SNP) | VAF 280/588 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.53); called by muse, mutect2, varscan2
- C4orf54 | c.156C>T p.A52= | Silent (SNP) | VAF 151/346 reads (44%) | catalogued as COSV72766832; called by muse, mutect2, varscan2
- CDHR5 | c.1725G>A p.P575= (on ENST00000358353 / NM_001171968.2; = p.P581= on NM_021924.5) | Silent (SNP) | VAF 211/508 reads (42%) | catalogued as rs772394034; called by muse, mutect2, varscan2
- CNPPD1 | c.318C>T p.L106= | Silent (SNP) | VAF 65/125 reads (52%) | called by muse, mutect2, varscan2
- CRAMP1 | c.873G>A p.A291= | Silent (SNP) | VAF 183/376 reads (49%) | catalogued as rs374300076; called by muse, mutect2, varscan2
- CYP27B1 | c.237C>T p.S79= | Silent (SNP) | VAF 208/484 reads (43%) | catalogued as rs1216687925; called by muse, mutect2, varscan2
- FBN3 | c.4125C>T p.N1375= | Silent (SNP) | VAF 46/101 reads (46%) | catalogued as rs184683769, COSV54466758; called by muse, mutect2
- FBXO27 | c.630C>T p.D210= | Silent (SNP) | VAF 119/282 reads (42%) | catalogued as rs552069426, COSV53072729; called by muse, mutect2, varscan2
- INSC | c.1182G>A p.A394= | Silent (SNP) | VAF 168/322 reads (52%) | catalogued as rs111784838, COSV65409956; called by muse, mutect2, varscan2
- KCNN2 | c.798C>G p.L266= (on ENST00000264773; = p.L478= on NM_021614.4) | Silent (SNP) | VAF 215/429 reads (50%) | called by muse, mutect2, varscan2
- LAMA2 | c.1599C>A p.T533= | Silent (SNP) | VAF 172/331 reads (52%) | called by muse, mutect2, varscan2
- LRWD1 | c.1563C>A p.I521= | Silent (SNP) | VAF 65/129 reads (50%) | called by muse, mutect2, varscan2
- NBAS | c.4704A>T p.A1568= | Silent (SNP) | VAF 177/376 reads (47%) | called by muse, mutect2, varscan2
- NLRP7 | c.543C>T p.G181= | Silent (SNP) | VAF 198/413 reads (48%) | catalogued as rs752629343, COSV60175839; called by muse, mutect2, varscan2
- NRG3 | c.423C>T p.S141= | Silent (SNP) | VAF 149/285 reads (52%) | catalogued as rs762036310, COSV64557583; called by muse, mutect2, varscan2
- PCDH19 | c.2703C>A p.G901= (on ENST00000373034 / NM_001184880.2; = p.G853= on NM_020766.3) | Silent (SNP) | VAF 346/738 reads (47%) | catalogued as rs748948987; called by muse, mutect2, varscan2
- PMEPA1 | c.699C>T p.S233= | Silent (SNP) | VAF 155/476 reads (33%) | catalogued as rs531021898, COSV99671749; called by muse, mutect2, varscan2
- PRAC1 | c.9C>T p.C3= | Silent (SNP) | VAF 90/220 reads (41%) | catalogued as COSV51704882, COSV99284881; called by muse, mutect2, varscan2
- PRDX3 | c.114G>A p.T38= | Silent (SNP) | VAF 202/481 reads (42%) | called by muse, mutect2, varscan2
- SCAND1 | c.117G>A p.S39= | Silent (SNP) | VAF 386/580 reads (67%) | catalogued as rs1056803764; called by muse, mutect2, varscan2
- SCN1B | c.376C>T p.L126= | Silent (SNP) | VAF 242/521 reads (46%) | called by muse, mutect2, varscan2
- SLC35A2 | c.30C>T p.T10= | Silent (SNP) | VAF 220/426 reads (52%) | catalogued as rs373480204; called by muse, varscan2
- TECTB | c.915A>G p.G305= | Silent (SNP) | VAF 45/115 reads (39%) | catalogued as rs775727136; called by muse, mutect2, varscan2
- TMTC1 | c.1179G>A p.P393= (on ENST00000539277 / NM_001193451.2; = p.P285= on NM_175861.3) | Silent (SNP) | VAF 179/401 reads (45%) | catalogued as rs372059579; called by muse, mutect2, varscan2
- WIZ | c.1863G>A p.E621= | Silent (SNP) | VAF 9/63 reads (14%) | catalogued as rs1364766940, COSV99653292; called by muse, varscan2
- ZFHX4 | c.5238G>A p.T1746= | Silent (SNP) | VAF 140/287 reads (49%) | catalogued as COSV50651121, COSV51492261; called by muse, mutect2, varscan2
- ZFP36L2 | c.36C>A p.V12= | Silent (SNP) | VAF 259/501 reads (52%) | called by muse, mutect2, varscan2
- ZNF676 | c.1560G>A p.T520= (on ENST00000650058; = p.T488= on NM_001001411.3) | Silent (SNP) | VAF 215/462 reads (47%) | catalogued as rs775446763, COSV101236103; called by muse, mutect2, varscan2
- ZNRF4 | c.57C>T p.A19= | Silent (SNP) | VAF 145/358 reads (41%) | catalogued as rs754163190; called by muse, mutect2, varscan2
- B3GAT1 | c.-22G>A | 5'UTR (SNP) | VAF 140/285 reads (49%) | catalogued as rs369890603; called by muse, mutect2, varscan2
- C19orf12 | chr19:29699079 A>G | 3'Flank (SNP) | VAF 64/153 reads (42%) | called by muse, mutect2, varscan2
- CHRNA4 | chr20:63361360 G>A | 5'Flank (SNP) | VAF 42/58 reads (72%) | catalogued as rs1431028402; called by muse, mutect2
- CLCN6 | c.2529+186A>C | Intron (SNP) | VAF 221/222 reads (100%) | called by muse, mutect2, varscan2
- DOK1 | c.-1C>A | 5'UTR (SNP) | VAF 148/282 reads (52%) | called by muse, varscan2
- GRID2 | chr4:92300870 G>C | 5'Flank (SNP) | VAF 99/192 reads (52%) | called by muse, mutect2, varscan2
- WASH8P | n.1405G>A | RNA (SNP) | VAF 248/1408 reads (18%) | catalogued as rs1421346215; called by muse, varscan2
- YWHAH | c.-60G>A | 5'UTR (SNP) | VAF 65/107 reads (61%) | called by muse, mutect2, varscan2
